Somatic mutation profile of tumor specimen TCGA-DD-AADL-01A (aliquot TCGA-DD-AADL-01A-11D-A40R-10) from TCGA case TCGA-DD-AADL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 58.9 years (21,512 days).
Specimen TCGA-DD-AADL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6eab190-3983-4146-b530-fcb35df3fbd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADL-10A (Blood Derived Normal), aliquot TCGA-DD-AADL-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f822ed20-e40d-4cd5-81ca-6df1b66014d7

The open-access MAF lists 141 somatic variants for this specimen: 107 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 30, Nonsense Mutation 7, Frame Shift Del 5, Frame Shift Ins 3, Intron 2, 3'UTR 2, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 66/96 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1544A>G p.N515S (on ENST00000404938 / NM_001163941.2; = p.N70S on NM_178559.6) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV99328673; called by muse, mutect2, varscan2
- ADCY8 | c.2092T>C p.S698P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99652696; called by muse, mutect2, varscan2
- ANKLE1 | c.1762G>T p.V588L (on ENST00000394458; = p.V534L on NM_152363.6) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs1383812974, COSV101082323; called by muse, mutect2
- ANKZF1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380582732, COSV99850626; called by muse, mutect2, varscan2
- ATP11B | c.472T>A p.L158M | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100017820, COSV100017854; called by muse, mutect2, varscan2
- BMP3 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV51082502, COSV99261762; called by muse, mutect2, varscan2
- C11orf24 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV58504861; called by muse, mutect2, varscan2
- C11orf24 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV100422602; called by muse, mutect2, varscan2
- CCDC186 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100991030; called by muse, mutect2, varscan2
- CCDC63 | c.1563C>A p.D521E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99960790; called by muse, mutect2, varscan2
- CCNA1 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV99714656; called by muse, mutect2, varscan2
- CEACAM3 | c.656C>G p.P219R | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99705002; called by muse, mutect2, varscan2
- CNTN5 | c.1365G>T p.M455I | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs775343047, COSV99678026; called by muse, mutect2, varscan2
- COPS7A | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99976497; called by muse, mutect2, varscan2
- CRYBA4 | c.189A>C p.Q63H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV100697811; called by muse, mutect2, varscan2
- CSMD2 | c.2186C>A p.T729N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99591386; called by muse, mutect2, varscan2
- CSNK1A1L | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.314); catalogued as COSV65789336, COSV65789752; called by muse, mutect2, varscan2
- CTDSP2 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101143020; called by muse, mutect2, varscan2
- CTNNA2 | c.738A>T p.Q246H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100784774; called by muse, mutect2, varscan2
- CYP4A22 | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV99595039; called by muse, mutect2, varscan2
- DHCR7 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs375187933; called by muse, mutect2, varscan2
- DOCK7 | c.5494-1G>T p.X1832_splice (on ENST00000635253 / NM_001367561.1; = p.X1801_splice on NM_033407.3) | Splice Site (SNP) | VAF 15/274 reads (5%) | catalogued as COSV52012223, COSV52016359; called by muse, mutect2
- DPY19L1 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 250/720 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100204757; called by muse, varscan2
- EDNRB | c.1112A>G p.Y371C (on ENST00000377211 / NM_001201397.1; = p.Y281C on NM_000115.5) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100526751; called by muse, mutect2, varscan2
- ELOA2 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs765195317, COSV99796917; called by muse, mutect2, varscan2
- EPB41 | c.2170C>A p.P724T (on ENST00000343067 / NM_001166005.2; = p.P482T on NM_004437.4) | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV100548826, COSV100549615; called by muse, mutect2, varscan2
- ESYT2 | c.761T>C p.V254A (on ENST00000613624; = p.V178A on NM_020728.3) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.79); PolyPhen benign (0.065); catalogued as COSV99276843; called by muse, mutect2, varscan2
- ETFBKMT | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100740383; called by muse, mutect2, varscan2
- FGFR1 | c.1722G>T p.Q574H (on ENST00000447712 / NM_023110.3; = p.Q572H on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100248518; called by muse, mutect2, varscan2
- FLG | c.6695G>T p.G2232V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV100911665; called by muse, mutect2, varscan2
- GABRQ | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941316, COSV64783630; called by muse, mutect2, varscan2
- GPR156 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs138857726; called by muse, mutect2, varscan2
- IDH1 | c.512A>C p.N171T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as COSV100576918, COSV61629615; called by muse, mutect2, varscan2
- KERA | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1256136822, COSV99899485; called by muse, mutect2
- KHDRBS2 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99834556; called by muse, mutect2
- KIAA1549L | c.5446G>T p.A1816S (on ENST00000321505; = p.A2113S on NM_012194.3) | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100381738; called by muse, mutect2, varscan2
- KPNA1 | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as COSV100724252; called by muse, mutect2, varscan2
- KRT5 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99358073; called by muse, mutect2, varscan2
- LBX1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1424100964, COSV100929944; called by muse, mutect2, varscan2
- LRFN1 | c.1709T>A p.V570D | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.379); catalogued as COSV99953038; called by muse, mutect2, varscan2
- LRRC32 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477021; called by muse, mutect2, varscan2
- LRRTM1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99702676; called by muse, mutect2, varscan2
- MAP3K19 | c.2593A>G p.N865D | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100208719; called by muse, mutect2, varscan2
- MAP3K4 | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.108); catalogued as COSV100815465; called by muse, mutect2, varscan2
- MIER1 | c.630T>A p.D210E (on ENST00000355356 / NM_001077701.3; = p.D227E on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100591048; called by muse, mutect2, varscan2
- MTARC1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV100856321; called by muse, mutect2, varscan2
- MYH14 | c.1964A>T p.D655V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99223066; called by muse, mutect2, varscan2
- MYH7 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100806225, COSV100806384; called by muse, mutect2, varscan2
- MYOG | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 61/154 reads (40%) | catalogued as COSV54096037, COSV99613979; called by muse, mutect2, varscan2
- NUP210L | c.2765T>C p.V922A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.501); catalogued as COSV99668297; called by muse, mutect2, varscan2
- OBSCN | c.19784T>C p.M6595T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100804256, COSV62301293; called by muse, mutect2, varscan2
- OR2L2 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100823856; called by muse, mutect2, varscan2
- ORC5 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99857094; called by muse, mutect2, varscan2
- ORC5 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99857096; called by muse, mutect2, varscan2
- PARP14 | c.5309A>G p.Y1770C | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101506291; called by muse, mutect2, varscan2
- PDZD2 | c.245C>G p.T82S | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV99225415; called by muse, mutect2, varscan2
- PIK3C2A | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs938273771, COSV99790876; called by muse, mutect2, varscan2
- PIK3CD | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100740251; called by muse, mutect2, varscan2
- PLXNB1 | c.1462T>A p.C488S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99602980; called by muse, mutect2, varscan2
- POLQ | c.7258T>A p.Y2420N | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952389; called by muse, mutect2, varscan2
- PPP1R3A | c.3029C>A p.P1010Q | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493160; called by muse, mutect2, varscan2
- PPRC1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.412); catalogued as COSV99531753; called by muse, mutect2, varscan2
- PRDM4 | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99946632; called by muse, mutect2, varscan2
- RASSF10 | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV61754622; called by muse, mutect2, varscan2
- SAMD12 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | catalogued as COSV100126205; called by muse, mutect2, varscan2
- SCRIB | c.4874T>C p.L1625P | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100253589; called by muse, mutect2, varscan2
- SCRIB | c.3941C>T p.P1314L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1159063077, COSV100253592; called by muse, mutect2, varscan2
- SEMA3A | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54867239; called by muse, mutect2, varscan2
- SEMA3A | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as COSV99547012; called by muse, mutect2, varscan2
- SEMA5B | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99532188; called by muse, mutect2, varscan2
- SETD1A | c.3601C>T p.R1201W | Missense Mutation (SNP) | VAF 83/109 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs774166831, COSV52685278; called by muse, mutect2, varscan2
- SEZ6L2 | c.1624G>T p.D542Y (on ENST00000308713 / NM_001114099.3; = p.D472Y on NM_012410.4) | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58100658; called by muse, mutect2, varscan2
- SIN3B | c.2994G>C p.E998D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV99931804, COSV99932152; called by muse, mutect2, varscan2
- SLC17A9 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV100947867; called by muse, mutect2
- SLCO2B1 | c.2105A>G p.K702R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.045); catalogued as COSV99214730; called by muse, mutect2, varscan2
- SLIT2 | c.4124G>A p.C1375Y | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884595; called by muse, mutect2, varscan2
- SLIT2 | c.4125C>A p.C1375* | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | catalogued as COSV99884597; called by muse, mutect2, varscan2
- SPPL2C | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100234072; called by muse, mutect2, varscan2
- SPTBN4 | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV100150696; called by muse, mutect2, varscan2
- STK11IP | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV99822977; called by muse, mutect2, varscan2
- TCAIM | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 123/363 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100703294; called by muse, mutect2, varscan2
- TLDC2 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99455988; called by muse, mutect2, varscan2
- TRIM32 | c.1894G>T p.V632F | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100528271; called by muse, mutect2, varscan2
- TRIM58 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.348); catalogued as COSV100825139, COSV63569431; called by muse, mutect2, varscan2
- TSC2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 45/60 reads (75%) | catalogued as rs45491095, CM981944, COSV99554411; ClinVar: not provided; called by muse, mutect2, varscan2
- TTN | c.71612T>A p.L23871H (on ENST00000591111; = p.L16447H on NM_003319.4) | Missense Mutation (SNP) | VAF 81/147 reads (55%) | PolyPhen probably damaging (0.988); catalogued as COSV100617652; called by muse, mutect2, varscan2
- UBL3 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as rs986288745, COSV101041636; called by muse, mutect2
- XIRP2 | c.8938C>T p.P2980S (on ENST00000628543; = p.P3155S on NM_152381.6) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV54680614, COSV99743958; called by muse, mutect2, varscan2
- YDJC | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1333688219, COSV99488946; called by muse, mutect2
- ZDHHC15 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 89/108 reads (82%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100973800; called by muse, varscan2
- ZFP36L1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100322733; called by muse, mutect2, varscan2
- ZNF141 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99549753; called by muse, mutect2, varscan2
- ZNF408 | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as COSV100305517; called by muse, mutect2, varscan2
- ZNF492 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101514010; called by muse, varscan2
- ZNF711 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 99/111 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52156660, COSV99341213; called by muse, mutect2, varscan2
- ARHGEF12 | c.1814_1817dup p.P607Efs*6 | Frame Shift Ins (INS) | VAF 46/110 reads (42%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.3548dup p.K1184Efs*12 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- ETNK1 | c.1072_*14del | Nonstop Mutation (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel
- FAM120A | c.1308del p.I437Sfs*79 | Frame Shift Del (DEL) | VAF 154/316 reads (49%) | called by mutect2, varscan2
- FAM153B | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MRNIP | c.709del p.R237Efs*98 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by pindel, varscan2
- NOSIP | c.76_91del p.S26Rfs*5 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- OR51A7 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2
- TAPBPL | c.821_833del p.T274Rfs*31 | Frame Shift Del (DEL) | VAF 49/121 reads (40%) | called by mutect2, pindel, varscan2
- TMCO6 | c.707_708insAGCAC p.L237Afs*81 | Frame Shift Ins (INS) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- WDR35 | c.759_762del p.M254Tfs*2 | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
- AMER3 | c.564G>A p.G188= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs777251443, COSV58465312; called by muse, mutect2, varscan2
- CST11 | c.48A>G p.L16= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs757399085, COSV100776869; called by muse, mutect2, varscan2
- DNAH5 | c.6315C>T p.A2105= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs1275214512, COSV99450785; called by muse, mutect2, varscan2
- DNAH9 | c.3864C>T p.D1288= | Silent (SNP) | VAF 53/63 reads (84%) | catalogued as rs778954683, COSV99306322; called by muse, mutect2, varscan2
- DOCK11 | c.204A>G p.P68= | Silent (SNP) | VAF 150/193 reads (78%) | catalogued as COSV99354066; called by muse, mutect2, varscan2
- FAT2 | c.7633C>A p.R2545= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs759347576, COSV55825923, COSV99943241; called by muse, mutect2, varscan2
- FLG | c.6696G>T p.G2232= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as COSV100911664; called by muse, mutect2, varscan2
- FURIN | c.2205C>T p.V735= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as rs762528103, COSV99184705; called by muse, mutect2, varscan2
- FXYD1 | c.147C>T p.I49= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99544918; called by muse, mutect2, varscan2
- GPR108 | c.1584A>G p.E528= (on ENST00000264080 / NM_001080452.1; = p.E286= on NM_020171.2) | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV99901397; called by muse, mutect2, varscan2
- GRN | c.483G>A p.R161= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs373703310; called by muse, mutect2, varscan2
- HOXA7 | c.219C>G p.G73= | Silent (SNP) | VAF 66/212 reads (31%) | catalogued as COSV54218846, COSV99636514, COSV99636525; called by muse, mutect2, varscan2
- MAP3K11 | c.2061G>T p.P687= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100442236; called by muse, mutect2, varscan2
- MICU2 | c.1053G>A p.K351= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV101212452; called by muse, mutect2, varscan2
- NLRP7 | c.903G>T p.T301= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100052867, COSV60172074; called by muse, mutect2
- OR10Z1 | c.264G>T p.G88= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1384111125, COSV63524735; called by muse, mutect2, varscan2
- OR2B3 | c.609T>C p.S203= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as rs759833609, COSV101013801; called by muse, mutect2, varscan2
- PCDHA9 | c.1620G>A p.A540= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs782367888, COSV65323524, COSV65330607; called by muse, mutect2, varscan2
- PCDHGA3 | c.1995C>T p.A665= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs1284650438, COSV99540186; called by muse, mutect2, varscan2
- PRAMEF17 | c.973C>T p.L325= | Silent (SNP) | VAF 46/293 reads (16%) | called by muse, mutect2, varscan2
- SEMG2 | c.186T>C p.S62= | Silent (SNP) | VAF 31/249 reads (12%) | catalogued as COSV101034112; called by muse, mutect2, varscan2
- SMCHD1 | c.4686A>G p.E1562= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV99861878; called by muse, mutect2, varscan2
- SPAG8 | c.468C>T p.G156= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99428057; called by muse, mutect2, varscan2
- SRCAP | c.5004T>C p.V1668= | Silent (SNP) | VAF 55/71 reads (77%) | catalogued as COSV99350400; called by muse, mutect2, varscan2
- SULT2A1 | c.12T>C p.D4= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV99705462; called by muse, mutect2, varscan2
- TMEM245 | c.846G>C p.L282= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as COSV101002367; called by muse, mutect2, varscan2
- USP10 | c.960A>G p.A320= | Silent (SNP) | VAF 43/59 reads (73%) | catalogued as rs771784330, COSV99551500; called by muse, mutect2, varscan2
- ZFYVE26 | c.2796G>A p.L932= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV100720501; called by muse, mutect2, varscan2
- ZNF551 | c.1614A>G p.K538= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99990048; called by muse, mutect2, varscan2
- ZNF831 | c.1143G>A p.P381= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs1018685125, COSV100926080; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3951G>T | Intron (SNP) | VAF 66/152 reads (43%) | catalogued as COSV100505636, COSV100506146; called by muse, mutect2, varscan2
- ORM1 | c.*2A>T | 3'UTR (SNP) | VAF 30/154 reads (19%) | called by mutect2, varscan2
- ORM2 | c.*2A>T | 3'UTR (SNP) | VAF 45/722 reads (6%) | called by muse, mutect2
- PHKB | c.76+2552G>A | Intron (SNP) | VAF 21/74 reads (28%) | catalogued as rs746670187, COSV54519295; called by muse, mutect2, varscan2
